Surgical pathology report (de-identified scan), TCGA case TCGA-QD-A8IV, project TCGA-THCA (Thyroid Carcinoma), tissue source site Emory University, specimen TCGA-QD-A8IV-01A (Primary Tumor).

[page 1 of 5]
Anat Path Reports

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

* Final Report *

(Verified)

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

Copy To Phys:

DOB:

Gender:

F

Acc #:

(Age:

Collected:

Received:

Reported:

Final Surgical Pathology Report

ICD-O-3
Carcinoma, papillary
thyroid 8260/3
Site: Thyroid C73.9
QW 4/14/14

Final Pathologic Diagnosis

A. THYROID, TOTAL THYROIDECTOMY:

- PAPILLARY THYROID CARCINOMA, MULTIFOCAL, INVOLVING LEFT LOBE AND ISTHMUS
- EXTRATHYROIDAL EXTENSION IS PRESENT
- PAPILLARY CARCINOMA FOCALLY EXTENDS TO MARGIN OF RESECTION
- METASTATIC PAPILLARY CARCINOMA IN THREE OF THREE LYMPH NODES (3/3) IDENTIFIED ADJACENT TO SUPERIOR LEFT THYROID LOBE
- ONE BENIGN PARATHYROID GLAND IS IDENTIFIED
- SEE SYNOPTIC REPORT

B. LYMPH NODES, LEFT NECK LEVEL 2:

- METASTATIC PAPILLARY THYROID CARCINOMA IN TWO OF TEN LYMPH NODES (2/10)

C. LYMPH NODES, LEFT NECK LEVEL 3:

- METASTATIC PAPILLARY THYROID CARCINOMA IN TWO OF TWO LYMPH NODES (2/2)
- A PATTERN OF EXTRANODAL EXTENSION IS PRESENT

Printed by:

Printed on:

[page 2 of 5]
Anat Path Reports

* Final Report *

D. LYMPH NODES, LEFT NECK LEVEL 4/5:

- METASTATIC PAPILLARY THYROID CARCINOMA IN SEVEN OF TWENTY TWO NODES (7/22)
- A PATTERN OF EXTRANODAL EXTENSION IS PRESENT

E. ANTERIOR THYROID TISSUE, RESECTION:

- FIBROADIPOSE TISSUE AND SKELETAL MUSCLE ONLY
- NO NEOPLASM IS PRESENT

F. LYMPH NODE, LEFT PARATRACHEAL:

- METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF ONE LYMPH NODE (1/1)

Comment: Drs. and have reviewed part A and concur.

Electronically Signed by .

BRAF Mutation Analysis / Review Pending

Synoptic Worksheet

A. Total thyroidectomy, stitch marks left superior lobe:

Procedure:	Total thyroidectomy
	Total thyroidectomy with left neck dissection
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	3.5 cm
	1.5 cm
	1.0 cm
	Left lobe:
	5.5 cm
	3.0 cm
	3.0 cm
	Isthmus +/- pyramidal lobe:
	3.0 cm
	1.5 cm
	1.5 cm
Tumor Focality:	Multifocal, Ipsilateral
	Multifocal, Midline (isthmus)
----- DOMINANT TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest Dimension: 1.6cm
Histologic Type:	Papillary carcinoma, classical (usual)
	Classical (papillary) architecture

Printed by:
Printed on:

Page 2 of 5
(Continued)

[page 3 of 5]
Anat Path Reports

* Final Report *

Margins:	Follicular architecture
Tumor Capsule:	Classical cytomorphology
Tumor Capsular Invasion:	Margins uninvolved by carcinoma
Lymph-Vascular Invasion:	None
Extrathyroidal Extension:	Cannot be assessed
	Not identified
	Present, minimal
----- SECOND TUMOR -----	
Tumor Laterality:	Isthmus
Tumor Size:	Greatest Dimension: 1.1cm
Histologic Type:	Papillary carcinoma, classical (usual)
	Classical (papillary) architecture
	Follicular architecture
	Classical cytomorphology
Margins:	Margin(s) involved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Cannot be assessed
Lymph-Vascular Invasion:	Not identified
Extrathyroidal Extension:	Present, minimal
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)
Regional Lymph Nodes (pN):	pN1b: Metastases to unilateral, bilateral or contralateral cervical (Levels I - V) or retropharyngeal or superior mediastinal lymph nodes (Level VII).
	Number of regional lymph nodes examined: 15
	Number of regional lymph nodes involved: 38
	Lymph Node, Extranodal Extension Present
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease
	Thyroiditis
	Parathyroid gland(s), within normal limits
Ancillary Studies:	Type: BRAF testing, to be separately reported

Clinical History

Multinodular goiter. Total thyroidectomy and central and left neck lymph node dissections.

Specimen(s) Received

A: Total thyroidectomy, stitch marks left superior lobe
B: Left neck level 2
C: Left neck level 3
D: Left neck level 4/5
E: Anterior thyroid tissue
F: Left paratracheal node

Printed by:
Printed on:

[page 4 of 5]
Anat Path Reports

* Final Report *

Gross Description

Specimen A is received fresh labeled with the patient's name, medical record number and "total thyroidectomy; stitch marks left superior lobe." Received are both right and left thyroid lobes and adjoining isthmus weighing collectively 59.9 grams and measuring 7.5 x 6.5 x 3.5 cm. The left thyroid lobe is 5.5 x 3.0 x 3.0 cm. The isthmus is 3.0 x 1.5 x 1.5 cm. The right thyroid lobe measures 3.5 x 1.5 x 1.0 cm. Identified on the left superior lobe of the left thyroid gland is a single stitch. No parathyroid tissue is grossly identified. Identified in the left thyroid gland is a firm, nodular, yellow, irregular mass measuring 3.5 x 1.9 x 2.6 cm. The mass appears to arise from the mid portion of the left thyroid gland and extend inferiorly, abutting the inferior surgical resection margin, within 2 mm of the margin. On serial sectioning, the mass appears to consist of both cystic and solid parts. The mass is also noted to be completely contained in the thyroid gland. Surrounding left thyroid parenchyma appears goitrous with multiple colloid nodules identified. The right thyroid gland as does the isthmus appears to have multiple colloid nodules as well with no dominant masses or colloid nodules identified. Surgical margins are inked black. (Dictated by Dr.

Specimen B is received in formalin labeled with the patient's name, medical record number and "left neck, level 2." Received is a specimen consisting of fibrofatty tissue with at least one identifiable lymph node measuring collectively 6.2 x 3.0 x 2.5 cm. Representative sections are submitted. (Dictated by Dr.

Specimen C is received in formalin labeled with the patient's name, medical record number and "left neck, level 3." Received is a specimen consisting of fibrofatty tissue and at least one large firm lymph node measuring collectively 2.6 x 2.2 x 1.8 cm. Upon serial sectioning identified what appear to be two possible lymph nodes with both firm, solid and cystic areas, concerning for involvement with tumor. The entire specimen is serially sectioned and submitted in its entirety. (Dictated by Dr.

Specimen D is received in formalin labeled with the patient's name, medical record number and "left neck, level 4/5." Received is a specimen consisting of fibrofatty tissue with multiple firm lymph nodes measuring collectively 4.8 x 3.2 x 3.0 cm. On further sectioning multiple large firm lymph nodes are found to be severely adhered to one another. A few select lymph nodes are separated and the rest of the specimen is serially sectioned collectively. (Dictated by Dr.

Specimen E is received in formalin labeled with the patient's name, medical record number and "anterior thyroid tissue." Received is a specimen measuring 4.0 x 2.5 x 1.3 cm. The specimen appears to consist of adipose tissue and identifiable small amounts of thyroid tissue. The specimen is submitted in its entirety. (Dictated by Dr.

Specimen F is received in formalin labeled with the patient's name, medical record number and "left paratracheal node." Received is a specimen consisting of a firm lymph node. The specimen is submitted in its entirety. (Dictated by Dr.

CASSETTE SUMMARY:

A1,A2:	Representative sections of right thyroid
A3:	Left thyroid inferior surgical resection margin
A4-A11:	Perpendicular sections of superior left thyroid resection margin
A12,A13:	Representative section of left thyroid mass
A14,A15:	Representative section of uninvolved left thyroid tissue
A16,A17:	Representative section of thyroid isthmus
A18:	Additional sections of right thyroid lobe (superior to inferior)
A19:	Additional sections of right thyroid lobe (superior to inferior)
A20:	Rest of right thyroid lobe submitted entirely (superior to inferior)
A21:	Additional sections of thyroid isthmus (superior to inferior)
A22:	Additional sections of thyroid isthmus (superior to inferior)

Printed by:
Printed on:

Page 4 of 5
(Continued)

[page 5 of 5]
Anat Path Reports

* Final Report *

A23: Additional sections of thyroid isthmus (superior to inferior)
A24: Additional sections of thyroid isthmus (superior to inferior)
A25: Additional sections of thyroid isthmus (superior to inferior)
A26: Additional sections of thyroid isthmus (superior to inferior)
A27: Additional sections of thyroid isthmus (superior to inferior)
A28: Rest of thyroid isthmus submitted entirely (superior to inferior)
A29: Additional section of left superior thyroid lobe mass (first ½)
A30: Additional section of left superior thyroid lobe mass (second ½)
A31: Remaining section of left superior thyroid lobe mass (first ½)
A32: Remaining section of left superior thyroid lobe mass (second ½)
A33: Superior thyroid mass and adjacent lymph node (first ½)
A34: Superior thyroid mass and adjacent lymph node (second ½)
B1: One bisected lymph node
B2: Three lymph nodes
B3: One lymph node, bisected
B4: One lymph node, bisected
B5: Two lymph nodes collectively bisected (first ½)
B6: Two lymph nodes collectively bisected (second ½)
B7: One lymph node, fragmented
B8: Representative section of muscle
C1-4: Serial sections of two lymph nodes largely replaced by tumor
D1: One bisected lymph node
D2: One bisected lymph node
D3: Two lymph nodes
D4-14: Serial sections of one large firm lymph node and multiple severely adhered smaller lymph nodes
E1-4: Serial sections of fibrofatty tissue and anterior thyroid tissue
F1: One lymph node, trisected

BRAF Mutation Analysis

Status: Review Pending

Printed by:
Printed on:

Page 5 of 5
(End of Report)

Criteria	hw 11/6/13	Yes	No

Source: NCI Genomic Data Commons file 19de8ff2-5a4f-4417-92cc-c20653c5506b (TCGA-QD-A8IV.9B35F0B4-C4E1-4EC4-9B58-550AC430984D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).